Surgical pathology report (de-identified scan), TCGA case TCGA-MZ-A5BI, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Montefiore Medical Center, specimen TCGA-MZ-A5BI-01A (Primary Tumor).

[page 1 of 2]
ICD 0-3
Carcinoma, squamous cell NOS
8870/3
Site: Tonsil NOS
C09.9
JW 6/18/13

Patient Name:

Requested By:

Ordered By:

Report Name:

Surg Path Case - STATUS: Final

**SEE NOTE

Collect/Perform:

Ordered By:

Ordered Date:

Facility:

Department: PATH

Physician Who Performed Procedure:

Requesting Physician:

SURGICAL PATHOLOGY,

.
. .
. .

DIAGNOSIS:

.
. .
. .

Left tonsil, excisional biopsy:

.
. .
. .

- Infiltrating squamous cell carcinoma, transitional type. See comment.

COMMENT:

Patient is part of an IRB-approved research protocol, ID=

.
. .
. .

CLINICAL INFORMATION:

year-old male with a preop diagnosis of tonsil mass.

.
. .
. .

GROSS DESCRIPTION:

.
. .
. .

Received fresh and labeled "left tonsillar mass" in a 3.2 x 2.2 x 2.0 cm, red-tan, irregular, rubbery, lobulated tissue. The specimen is serially sectioned to reveal tan-red, lobulated, rubbery cut surfaces. The specimen is submitted entirely in four cassettes.

.
. .
. .
. .

Electronic Signature

.
. .
. .

[page 2 of 2]
Patient Name:

Requested By:

Ordered By:

Report Name: :

The Attending Pathologist reviewed this case and made the diagnosis.

Where applicable, immunohistochemistry and in situ hybridization tests were developed and the performance characteristics determined by the

These tests have not been cleared or approved by the US Food and Drug Administration and the results should be correlated with other clinical and laboratory data. Appropriate controls were performed for all immunohistochemistry, in situ hybridization and histochemical tests.

Pg. 2 of 2

Source: NCI Genomic Data Commons file 305e9da0-e33e-451a-83c3-d9b2270ca5a0 (TCGA-MZ-A5BI.EFB01C57-A774-4310-95CD-2AAF379ACB79.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).